Somatic mutation profile of tumor specimen 0DBM1E from CCDI case PBBLEW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.8 years (2,466 days).
Specimen 0DBM1E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a911374-e32e-4ba1-88a6-933f72c7b12c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBM1F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/feb618b8-d50a-43b7-bf3a-24b52829c556

The open-access MAF lists 29 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Intron 4, 5'UTR 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC124 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 115/424 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs945309906, COSV71490503; called by muse, mutect2, varscan2
- DGKZ | c.2267C>T p.T756M (on ENST00000454345 / NM_001105540.2; = p.T568M on NM_003646.4) | Missense Mutation (SNP) | VAF 17/619 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.455); catalogued as COSV100552225; called by muse, mutect2
- DNAH6 | c.7309C>T p.R2437C | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1224956365; called by muse, mutect2, varscan2
- FAM83C | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 38/855 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs755472776, COSV65582814; called by muse, mutect2
- FGD5 | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 244/589 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200418068, COSV53245646; called by muse, mutect2, varscan2
- KLHL3 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 40/838 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as rs1047707196, COSV59054389; called by muse, mutect2
- PLD6 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 285/727 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs201208806; called by muse, mutect2, varscan2
- ADGRB1 | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 16/618 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2
- BIRC3 | c.1575A>T p.L525F | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.432); called by muse, mutect2
- FSTL4 | c.1048C>A p.Q350K | Missense Mutation (SNP) | VAF 14/545 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- GATA6 | c.1484C>A p.P495H | Missense Mutation (SNP) | VAF 24/720 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- HSPA6 | c.1642G>C p.V548L | Missense Mutation (SNP) | VAF 124/675 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MMGT1 | c.237-1G>T p.X79_splice | Splice Site (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- PHF7 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 108/515 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RYR1 | c.3974C>T p.A1325V | Missense Mutation (SNP) | VAF 122/507 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ULK4 | c.3637C>T p.P1213S | Missense Mutation (SNP) | VAF 195/732 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANK2 | c.639G>A p.Q213= | Silent (SNP) | VAF 72/1130 reads (6%) | catalogued as COSV100000644; called by muse, mutect2
- KBTBD4 | c.1416T>C p.C472= | Silent (SNP) | VAF 105/365 reads (29%) | called by muse, mutect2, varscan2
- LY9 | c.945C>A p.V315= | Silent (SNP) | VAF 132/485 reads (27%) | catalogued as COSV54432509; called by muse, mutect2, varscan2
- MARCHF4 | c.720C>T p.A240= | Silent (SNP) | VAF 40/515 reads (8%) | catalogued as rs920882160, COSV56107705, COSV99814809; called by muse, mutect2
- PCED1B | c.789C>T p.G263= | Silent (SNP) | VAF 28/494 reads (6%) | catalogued as rs373212050; called by muse, mutect2
- POU2F3 | c.564C>T p.L188= | Silent (SNP) | VAF 256/594 reads (43%) | catalogued as rs370431541, COSV52797078; called by muse, varscan2
- PPFIA1 | c.3264C>T p.F1088= | Silent (SNP) | VAF 162/565 reads (29%) | catalogued as rs778146650; called by muse, mutect2, varscan2
- ANKRD10 | c.456-912T>A | Intron (SNP) | VAF 325/882 reads (37%) | called by muse, mutect2, varscan2
- APP | c.58-28137T>C | Intron (SNP) | VAF 43/149 reads (29%) | catalogued as rs867968568; called by muse, mutect2, varscan2
- ELOB | c.4-48C>T | Intron (SNP) | VAF 8/108 reads (7%) | catalogued as rs1227525930; called by muse, mutect2
- FBXO9 | c.-85T>C | 5'UTR (SNP) | VAF 14/234 reads (6%) | called by muse, mutect2
- KRTAP21-1 | c.*84C>A | 3'UTR (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- WDR18 | c.741+18C>T | Intron (SNP) | VAF 320/719 reads (45%) | catalogued as rs761636839; called by muse, mutect2, varscan2
